Somatic mutation profile of tumor specimen 0DUETU from CCDI case PBCKYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.5 years (3,463 days).
Specimen 0DUETU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca721cd-c404-4f20-a7f6-2f942356ee0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1388ef0-042a-4017-8bc3-4fcbea3651bd

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPEPPS | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 120/528 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1250491673; called by muse, mutect2, varscan2
- SP3 | c.1934A>G p.H645R | Missense Mutation (SNP) | VAF 189/1551 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329573694; called by muse, mutect2, varscan2
- IP6K2 | c.820A>C p.K274Q | Missense Mutation (SNP) | VAF 331/938 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR2F6 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RSBN1L | c.2222A>G p.D741G | Missense Mutation (SNP) | VAF 467/1300 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SURF4 | c.147C>T p.S49= | Silent (SNP) | VAF 488/1304 reads (37%) | catalogued as rs782367838, COSV64339016; called by muse, mutect2, varscan2
- ILDR2 | c.*64C>T | 3'UTR (SNP) | VAF 116/408 reads (28%) | called by muse, mutect2, varscan2
- ISL2 | c.59-85C>A | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- PFKFB2 | c.*71T>C | 3'UTR (SNP) | VAF 12/337 reads (4%) | called by muse, mutect2
